Somatic mutation profile of tumor specimen TCGA-LA-A446-01A (aliquot TCGA-LA-A446-01A-21D-A257-08) from TCGA case TCGA-LA-A446, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.0 years (25,199 days).
Specimen TCGA-LA-A446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d335357-0873-4d0a-8267-6a5a58d799ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LA-A446-10A (Blood Derived Normal), aliquot TCGA-LA-A446-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3d25a4c-b7d4-45bc-a6d3-4b82e82cd8a2

The open-access MAF lists 351 somatic variants for this specimen: 267 protein-altering or splice-affecting, 71 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 71, Nonsense Mutation 9, Splice Site 8, Frame Shift Del 7, Intron 4, RNA 4, Splice Region 3, 5'UTR 2, Translation Start Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 29/83 reads (35%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 184/367 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100735641, COSV62931382; called by muse, mutect2, varscan2
- ABCB1 | c.531-1G>T p.X177_splice | Splice Site (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99711909; called by muse, mutect2, varscan2
- ABCC12 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs775731661, COSV100252062; called by muse, mutect2, varscan2
- ABCD2 | c.2003+1G>A p.X668_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as rs765947271, COSV100429091, COSV58053569; called by muse, mutect2, varscan2
- ACSS1 | c.1707C>T p.I569= | Splice Region (SNP) | VAF 20/117 reads (17%) | catalogued as rs373928802; called by muse, mutect2, varscan2
- ACTRT1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs1305195346, COSV100947484; called by muse, mutect2, varscan2
- ADAMTS18 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.824); catalogued as COSV99270928; called by muse, mutect2, varscan2
- ADCY5 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1199524320, COSV101518386; called by muse, mutect2, varscan2
- ADGRG4 | c.2406G>T p.E802D | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99794158; called by muse, mutect2, varscan2
- AGMO | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866158456, COSV61123949; called by muse, mutect2, varscan2
- AGTR1 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.301); catalogued as rs1047885033, COSV100836912; called by muse, mutect2, varscan2
- AICDA | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV99983947; called by muse, mutect2, varscan2
- ALLC | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV52998359, COSV99377356; called by muse, mutect2, varscan2
- ALX4 | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100240841; called by muse, mutect2, varscan2
- AMY2A | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV70214793; called by muse, mutect2, varscan2
- ANK2 | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99999111; called by muse, mutect2, varscan2
- ANO3 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99880025; called by muse, mutect2, varscan2
- ANP32E | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV100029530; called by muse, mutect2, varscan2
- ARHGAP35 | c.1757A>C p.Q586P | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV101350644; called by muse, mutect2, varscan2
- ASH1L | c.2379A>T p.L793F | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100853061; called by muse, mutect2, varscan2
- ASIC2 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV100725438, COSV100726924; called by muse, mutect2, varscan2
- ATP10D | c.2269G>C p.A757P | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375583564; called by muse, mutect2, varscan2
- ATP13A5 | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as COSV100664652; called by muse, mutect2, varscan2
- ATP1B4 | c.347A>C p.Y116S (on ENST00000218008 / NM_001142447.3; = p.Y112S on NM_012069.5) | Missense Mutation (SNP) | VAF 131/190 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486092; called by muse, mutect2, varscan2
- ATP8A1 | c.2771C>A p.P924H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100044679; called by muse, mutect2, varscan2
- ATP8B4 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52713194, COSV99463125; called by muse, mutect2, varscan2
- BBS4 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756091833, COSV99166375; called by muse, mutect2, varscan2
- BBS9 | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as rs1275635091, COSV99625484; called by muse, mutect2, varscan2
- BIRC6 | c.13677C>A p.Y4559* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV101427748; called by muse, mutect2, varscan2
- C18orf25 | c.1024A>T p.R342W | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99959751; called by muse, mutect2
- C19orf44 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99522026; called by muse, mutect2, varscan2
- C1GALT1C1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV100485555; called by muse, mutect2, varscan2
- CCAR2 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99254415; called by muse, mutect2, varscan2
- CCAR2 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV99254416; called by muse, varscan2
- CCDC38 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100717297; called by muse, mutect2, varscan2
- CCDC63 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100370146, COSV57527642; called by muse, mutect2, varscan2
- CD163L1 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58014589; called by muse, mutect2, varscan2
- CDC5L | c.2398T>A p.S800T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV101014838; called by muse, mutect2, varscan2
- CDH10 | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV100049786; called by muse, mutect2, varscan2
- CDH19 | c.1378G>C p.V460L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV100050667, COSV50964615; called by muse, mutect2, varscan2
- CENPE | c.4354G>C p.E1452Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV99476792; called by muse, mutect2, varscan2
- CEP72 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99374403; called by muse, varscan2
- CHRNA7 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.155); catalogued as rs1226473726, COSV100180677; called by mutect2, varscan2
- CLIP4 | c.974A>T p.N325I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100191336; called by muse, mutect2, varscan2
- CLMN | c.2089T>G p.L697V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100111930; called by muse, mutect2, varscan2
- COL6A3 | c.8263G>T p.A2755S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99795962; called by muse, mutect2, varscan2
- COL9A1 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293861; called by muse, mutect2, varscan2
- CPLX3 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100547515; called by muse, mutect2, varscan2
- CPSF3 | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99432387; called by muse, mutect2, varscan2
- CR2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs764660492, COSV100889509; called by muse, mutect2, varscan2
- CRISP2 | c.90A>T p.L30F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100188866; called by muse, mutect2, varscan2
- CSMD3 | c.10018T>C p.S3340P (on ENST00000297405 / NM_001363185.1; = p.S3171P on NM_052900.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV99822132; called by muse, mutect2, varscan2
- CSTF1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99410070; called by muse, mutect2
- CTLA4 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV99865044; called by muse, mutect2, varscan2
- CUX2 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99918411; called by muse, mutect2
- CXorf21 | c.172T>G p.C58G | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV100973206; called by muse, mutect2
- CYBB | c.1639A>T p.S547C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as COSV101059671; called by muse, mutect2, varscan2
- CYP39A1 | c.1169G>T p.W390L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99241782; called by muse, mutect2, varscan2
- DAPK3 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100009433; called by muse, mutect2, varscan2
- DCDC1 | c.90A>T p.Q30H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV60860823; called by muse, mutect2, varscan2
- DCSTAMP | c.195G>C p.W65C | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99885987; called by muse, mutect2, varscan2
- DDHD1 | c.1867G>T p.D623Y (on ENST00000323669; = p.D820Y on NM_030637.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211698885, COSV100078937; called by muse, mutect2, varscan2
- DDX23 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV57282150, COSV57284805; called by muse, mutect2, varscan2
- DIP2C | c.2918C>T p.S973L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV55153144; called by muse, mutect2, varscan2
- DLG4 | c.2144A>G p.Y715C (on ENST00000399506 / NM_001321075.3; = p.Y758C on NM_001365.4) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV100263371; called by muse, mutect2, varscan2
- DMBT1 | c.5795G>T p.R1932L (on ENST00000338354 / NM_001377530.1; = p.R1175L on NM_004406.3) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.362); catalogued as COSV100351873; called by muse, mutect2, varscan2
- DNAH11 | c.7249A>C p.T2417P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100176466; called by muse, mutect2
- DNAH8 | c.2561C>A p.T854K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100542919; called by muse, mutect2, varscan2
- DNAH8 | c.7938G>T p.K2646N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542920; called by muse, mutect2, varscan2
- DNAH8 | c.9282G>C p.E3094D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as COSV100542923; called by muse, mutect2, varscan2
- DOCK2 | c.4995-1G>C p.X1665_splice | Splice Site (SNP) | VAF 49/113 reads (43%) | catalogued as COSV99909773; called by muse, mutect2, varscan2
- DOP1B | c.1401C>G p.N467K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101214936; called by muse, mutect2, varscan2
- DYNC2H1 | c.10930G>A p.D3644N | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.261); catalogued as COSV100517240; called by muse, mutect2, varscan2
- EDNRB | c.857G>T p.S286I (on ENST00000377211 / NM_001201397.1; = p.S196I on NM_000115.5) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM056581, CM101981, COSV100526128; called by muse, mutect2, varscan2
- EDRF1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100523132, COSV100523964; called by muse, mutect2, varscan2
- EPHA5 | c.2790C>A p.N930K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV99895477; called by muse, mutect2, varscan2
- ERBB4 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV61477791; called by muse, mutect2, varscan2
- EXOSC4 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV100283944; called by muse, mutect2, varscan2
- FAM214A | c.1931G>T p.C644F | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs779015033, COSV55924783, COSV99957513; called by muse, mutect2, varscan2
- FAT3 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV99960845; called by muse, mutect2, varscan2
- FCRL5 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 47/95 reads (49%) | catalogued as COSV100708446, COSV62516624; called by muse, mutect2, varscan2
- FGB | c.1203C>A p.N401K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs771728339, COSV57419656; called by muse, mutect2, varscan2
- FIGNL1 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV63554156; called by muse, mutect2, varscan2
- FIP1L1 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100184121; called by muse, mutect2, varscan2
- FLT1 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99147129; called by muse, mutect2, varscan2
- FOLH1 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV99922584; called by muse, mutect2, varscan2
- FRMPD1 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1461652675, COSV100899226; called by muse, mutect2, varscan2
- FSHR | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV100436397; called by muse, mutect2, varscan2
- GABRA6 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200373173, COSV50877577, COSV50900675; called by muse, mutect2, varscan2
- GDF5 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs750789307, COSV100976704; called by muse, mutect2, varscan2
- GFAP | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99492971; called by muse, mutect2, varscan2
- GNAL | c.329A>C p.E110A (on ENST00000269162 / NM_001142339.3; = p.E187A on NM_182978.4) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99302941; called by muse, mutect2, varscan2
- GOLM2 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100247613; called by muse, mutect2, varscan2
- GPC5 | c.1380T>A p.D460E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV100992552; called by muse, mutect2, varscan2
- GPR55 | c.695T>A p.L232Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101235644; called by muse, mutect2, varscan2
- GPR55 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101235645; called by muse, mutect2, varscan2
- GPR78 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs770041034, COSV101223909; called by muse, mutect2, varscan2
- GRIN2A | c.4250G>T p.R1417L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as COSV100407857, COSV58026755; called by muse, mutect2, varscan2
- GRIP1 | c.2269+2T>A p.X757_splice (on ENST00000359742 / NM_001379345.1; = p.X705_splice on NM_021150.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 24/137 reads (18%) | catalogued as COSV99667696; called by muse, mutect2, varscan2
- HCN1 | c.2468C>A p.P823H | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100298017, COSV57531605; called by muse, mutect2, varscan2
- HMGN1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.825); catalogued as COSV99903224; called by muse, mutect2, varscan2
- HTATSF1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV99511357; called by muse, mutect2, varscan2
- HTR3E | c.916C>A p.P306T (on ENST00000415389 / NM_001256613.1; = p.P321T on NM_182589.2) | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs745452347, COSV100093609; called by muse, mutect2, varscan2
- HYAL4 | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99772011; called by muse, mutect2, varscan2
- KCNH2 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV100058912; called by muse, mutect2, varscan2
- KCNK10 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100067089; called by muse, mutect2, varscan2
- KIAA0319 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100985130, COSV100985815; called by muse, mutect2, varscan2
- KIAA1210 | c.4724A>T p.E1575V | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101273885; called by muse, mutect2, varscan2
- KIAA1755 | c.1478A>T p.H493L | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99641361; called by muse, mutect2, varscan2
- KIF19 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100738892, COSV63428833; called by muse, mutect2, varscan2
- L1CAM | c.3127T>A p.C1043S | Missense Mutation (SNP) | VAF 95/148 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100648823; called by muse, mutect2, varscan2
- LACRT | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV99143788; called by muse, mutect2, varscan2
- LDLR | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV99369440; called by muse, mutect2, varscan2
- LONRF1 | c.1584G>T p.R528S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101238159; called by muse, mutect2, varscan2
- LPL | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as CD145348, COSV100255206; called by muse, mutect2, varscan2
- LRRC66 | c.2198A>G p.E733G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100602792; called by muse, mutect2, varscan2
- LRRIQ1 | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV101277689; called by muse, mutect2, varscan2
- LRRTM1 | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54441703; called by muse, mutect2, varscan2
- LTA4H | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs530290388, COSV99956867; called by muse, mutect2, varscan2
- MACF1 | c.18845A>G p.K6282R (on ENST00000372915; = p.K4327R on NM_012090.5) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs141128754; called by muse, mutect2, varscan2
- MAMLD1 | c.1981G>T p.G661W | Missense Mutation (SNP) | VAF 84/125 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99475459; called by muse, mutect2, varscan2
- MAN2A1 | c.1042A>T p.M348L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV99810309; called by muse, mutect2, varscan2
- MAN2A1 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs754216087, COSV54858567; called by muse, mutect2, varscan2
- MAP1A | c.5852C>T p.P1951L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.181); catalogued as rs768903001, COSV55807032; called by muse, mutect2, varscan2
- MAP3K21 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100786064; called by muse, mutect2, varscan2
- MIEF1 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100307502; called by muse, mutect2, varscan2
- MITF | c.580-2A>T p.X194_splice (on ENST00000448226 / NM_006722.3; = p.X88_splice on NM_000248.4) | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100096389; called by muse, mutect2, varscan2
- MLST8 | c.343A>T p.R115W | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100063025; called by muse, mutect2, varscan2
- MMS22L | c.891G>T p.W297C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245942; called by muse, mutect2, varscan2
- MMS22L | c.890G>C p.W297S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99245944; called by muse, mutect2, varscan2
- MOXD1 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs763548180, COSV60945155; called by muse, mutect2
- MSRA | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV100412209; called by muse, mutect2, varscan2
- MUC16 | c.23092T>A p.S7698T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV101197667; called by muse, mutect2, varscan2
- MUC17 | c.12844C>A p.Q4282K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV100071322; called by muse, mutect2
- MYBL1 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101576450; called by muse, varscan2
- MYO16 | c.675+2T>A p.X225_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99193430; called by muse, mutect2, varscan2
- NDST4 | c.838C>A p.H280N | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as COSV99995236; called by muse, mutect2, varscan2
- NEFM | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99646876; called by muse, mutect2, varscan2
- NEFM | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99646879; called by muse, varscan2
- NFKB1 | c.556C>T p.R186W (on ENST00000394820 / NM_001382627.1; = p.R187W on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99896544; called by muse, mutect2, varscan2
- NGDN | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101238821; called by muse, mutect2, varscan2
- NNT | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.876); catalogued as COSV99238287; called by muse, mutect2, varscan2
- NRCAM | c.3484G>A p.V1162M (on ENST00000379028 / NM_001371124.1; = p.V1041M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100694117; called by muse, mutect2
- NUP133 | c.2978A>G p.E993G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as COSV99772483; called by muse, mutect2, varscan2
- OR2G3 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180452; called by muse, mutect2, varscan2
- OR51A4 | c.224T>A p.L75* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as COSV100985157; called by muse, mutect2, varscan2
- OR51T1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100434258; called by muse, mutect2, varscan2
- OR52B4 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV101281567; called by muse, mutect2
- OR6C74 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs1263802252, COSV100667638; called by muse, mutect2, varscan2
- OR9K2 | c.305T>C p.I102T (on ENST00000305377; = p.I80T on NM_001005243.1) | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs886115537, COSV100543721; called by muse, mutect2
- PCCA | c.1201T>A p.Y401N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100886428; called by muse, mutect2, varscan2
- PCF11 | c.2021C>G p.S674C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100017678; called by muse, mutect2, varscan2
- PCNT | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- PDIA5 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV100299092; called by muse, mutect2, varscan2
- PENK | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100152100, COSV59239901; called by muse, mutect2, varscan2
- PGM2L1 | c.294C>G p.Y98* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as COSV99994524; called by muse, mutect2, varscan2
- PHRF1 | c.3287C>A p.P1096H (on ENST00000264555 / NM_001286581.2; = p.P1095H on NM_020901.4) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV99199368; called by muse, mutect2, varscan2
- PI4K2A | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101034060; called by muse, mutect2, varscan2
- PLB1 | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100577411, COSV59832714; called by muse, mutect2, varscan2
- PLEC | c.13394A>G p.E4465G (on ENST00000322810 / NM_201380.4; = p.E4355G on NM_000445.5) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100509563; called by muse, mutect2, varscan2
- PLEKHA8 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99321287; called by muse, mutect2, varscan2
- PLXNA2 | c.4682C>T p.A1561V | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100884981; called by muse, mutect2, varscan2
- POU5F1 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52563934; called by muse, mutect2, varscan2
- PPP1R3A | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as COSV52891808; called by muse, mutect2, varscan2
- PPP2R5A | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV99806386; called by muse, mutect2, varscan2
- PROS1 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs372589167; called by muse, mutect2
- PROX1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99798570; called by muse, mutect2, varscan2
- PRSS35 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100864011; called by muse, mutect2, varscan2
- PTPRC | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100722025; called by muse, mutect2
- RAG2 | c.960C>A p.S320R | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV100271001; called by muse, mutect2, varscan2
- RAI1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1376549670, COSV99883091, COSV99883131; called by muse, mutect2, varscan2
- RAP2B | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV100058819; called by muse, mutect2
- RD3 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100879185; called by muse, mutect2, varscan2
- RET | c.2935G>C p.E979Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100392049; called by muse, mutect2, varscan2
- RFX6 | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1465589580, COSV100263078; called by muse, mutect2, varscan2
- RFX6 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100263083; called by muse, mutect2, varscan2
- RNF115 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100991548; called by muse, mutect2, varscan2
- RPGRIP1L | c.1733A>T p.Q578L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as COSV100045683; called by muse, mutect2, varscan2
- RPS6KA6 | c.1418G>C p.R473P | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53122968, COSV99423962; called by muse, mutect2, varscan2
- RTTN | c.4565-2A>C p.X1522_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99730697; called by muse, mutect2, varscan2
- S1PR1 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513597, COSV59514436; called by muse, mutect2, varscan2
- SCML2 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV99318476; called by muse, mutect2, varscan2
- SELENON | c.1552A>T p.K518* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100823433; called by muse, mutect2, varscan2
- SERPINB7 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100320352; called by muse, mutect2, varscan2
- SH3GL2 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101013966; called by muse, mutect2, varscan2
- SIAE | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs527559371, COSV99422107; called by muse, mutect2, varscan2
- SIGLEC6 | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as COSV100585119, COSV58435663; called by muse, mutect2, varscan2
- SLC25A31 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55421816; called by muse, mutect2, varscan2
- SLC26A1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV99925590; called by muse, mutect2, varscan2
- SLC2A12 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99259565; called by muse, mutect2, varscan2
- SLC2A14 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs374655537, COSV100533574, COSV61585766; called by muse, mutect2, varscan2
- SLC34A2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs560657112, COSV101158196, COSV65940727; called by muse, mutect2, varscan2
- SLC43A1 | c.1194G>T p.R398S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV99560713; called by muse, mutect2, varscan2
- SLC4A11 | c.162C>A p.D54E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV101195871; called by muse, mutect2, varscan2
- SLC5A8 | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101610506; called by muse, mutect2, varscan2
- SLCO1C1 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99858311; called by muse, mutect2, varscan2
- SMCHD1 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV99860320; called by muse, mutect2, varscan2
- SORL1 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV99492649; called by muse, mutect2, varscan2
- SOX13 | c.7A>C p.M3L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99689833; called by muse, varscan2
- SPACA1 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV99389352; called by muse, mutect2, varscan2
- SPEF2 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99213470; called by muse, mutect2, varscan2
- SPHKAP | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1167308953, COSV60881758, COSV60891098; called by muse, mutect2, varscan2
- SPTBN1 | c.4010G>T p.G1337V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100441582; called by muse, mutect2, varscan2
- SRRT | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.024); catalogued as rs769951704, COSV61451248; called by muse, mutect2, varscan2
- SSTR1 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as rs765170816, COSV99942652; called by muse, mutect2
- ST3GAL1 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | PolyPhen probably damaging (0.993); catalogued as COSV100171747, COSV60613113; called by muse, mutect2, varscan2
- STXBP2 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99656888; called by muse, mutect2, varscan2
- TAAR6 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as COSV99256433; called by muse, mutect2, varscan2
- TAF1 | c.3072G>T p.M1024I (on ENST00000373790 / NM_138923.4; = p.M1045I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV99334238; called by muse, mutect2, varscan2
- TBATA | c.97A>T p.R33W | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.28); catalogued as COSV100165093, COSV54720260; called by muse, mutect2, varscan2
- TBC1D28 | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs574074719, COSV100560883; called by muse, mutect2, varscan2
- TECPR1 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101130213; called by muse, mutect2
- TGFB1I1 | c.1169G>T p.R390L (on ENST00000394863 / NM_001042454.3; = p.R373L on NM_015927.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.116); catalogued as COSV100690886; called by muse, mutect2, varscan2
- TICRR | c.2488A>G p.S830G | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99175983; called by muse, mutect2, varscan2
- TMEM225 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100902733; called by muse, mutect2, varscan2
- TMEM268 | c.707T>A p.M236K | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV99938572; called by muse, mutect2, varscan2
- TMEM9 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201591838, COSV100947339; called by muse, mutect2, varscan2
- TRHDE | c.2931+1G>A p.X977_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99668708; called by muse, mutect2, varscan2
- TRIB3 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV99423574; called by muse, mutect2, varscan2
- TRIM2 | c.1120G>T p.G374W (on ENST00000437508; = p.G401W on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107466, COSV100107917; called by muse, mutect2, varscan2
- TRIM41 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100162857; called by muse, mutect2, varscan2
- TRIO | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100709686; called by muse, mutect2, varscan2
- TROAP | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99226630; called by muse, mutect2, varscan2
- TROAP | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV99226632; called by muse, mutect2, varscan2
- TRPM6 | c.3700G>A p.D1234N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.367); catalogued as rs375797671; called by muse, mutect2, varscan2
- TTN | c.91044C>A p.N30348K (on ENST00000591111; = p.N22924K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | PolyPhen probably damaging (0.998); catalogued as COSV100591251; called by muse, mutect2, varscan2
- VSTM1 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1314049349, COSV58074277; called by muse, mutect2
- WASF1 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV99660989; called by muse, mutect2, varscan2
- WASL | c.1320G>C p.Q440H | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99771440; called by muse, mutect2, varscan2
- WNT5B | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV100148534; called by muse, mutect2, varscan2
- XIRP2 | c.4904C>T p.P1635L (on ENST00000628543; = p.P1810L on NM_152381.6) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99737479; called by muse, mutect2, varscan2
- XKR3 | c.262T>C p.F88L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV100509099; called by muse, mutect2, varscan2
- XPR1 | c.2066A>T p.D689V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV100851402; called by muse, mutect2, varscan2
- ZFPM2 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs759870308, COSV65873114, COSV65875319; called by muse, mutect2, varscan2
- ZNF132 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs1222913417, COSV99570966; called by muse, varscan2
- ZNF214 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV99547093; called by muse, mutect2, varscan2
- ZNF214 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.82); catalogued as rs61745735; called by muse, mutect2, varscan2
- ZNF430 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV99841512; called by muse, mutect2, varscan2
- ZNF471 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.097); catalogued as rs757915725, COSV100340304; called by muse, mutect2, varscan2
- ZNF479 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58637839, COSV58638243; called by muse, mutect2, varscan2
- ZNF479 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100482398; called by muse, mutect2, varscan2
- ZNF492 | c.1226C>A p.T409N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as COSV101513925; called by muse, mutect2, varscan2
- ZNF516 | c.2869C>A p.P957T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV101487183, COSV101487254, COSV71587068; called by muse, mutect2, varscan2
- ZNF536 | c.1747G>T p.V583F | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as COSV100834520; called by muse, mutect2, varscan2
- ZNF600 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV100592879, COSV57745109; called by muse, mutect2, varscan2
- ZNF667 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs1439906639, COSV99409948; called by muse, mutect2, varscan2
- ZNF835 | c.1452C>A p.S484R | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); catalogued as COSV101606244; called by muse, mutect2, varscan2
- ZNF98 | c.1469A>G p.Y490C | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as rs1390271412, COSV100757251, COSV100757258; called by muse, mutect2
- ZPLD1 | c.-8G>T | Splice Region (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100082850; called by muse, mutect2
- ZWINT | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100571467; called by muse, mutect2, varscan2
- ADAD2 | c.1174_1182del p.G392_L394del (on ENST00000315906 / NM_001145400.2; = p.G474_L476del on NM_139174.4) | In Frame Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | called by mutect2, pindel, varscan2
- FGF14 | c.713del p.G238Afs*23 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- GDF10 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); called by muse, mutect2
- ISL1 | c.974del p.G325Afs*4 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- MRC1 | c.3244C>G p.R1082G | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFATC1 | c.480del p.S161Afs*11 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- PKD1L1 | c.5867_5868del p.R1956Pfs*77 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2
- SEMA5B | c.528del p.K177Rfs*13 | Frame Shift Del (DEL) | VAF 29/57 reads (51%) | called by mutect2, pindel, varscan2
- SIPA1L3 | c.4179_4181dup p.G1394dup | In Frame Ins (INS) | VAF 16/24 reads (67%) | called by mutect2, varscan2
- TFAP2B | c.869_911del p.K290Mfs*16 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | called by mutect2, pindel
- TRBC2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV28 | c.301dup p.S101Kfs*? | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD42 | c.690A>G p.L230= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99473466; called by muse, mutect2, varscan2
- ATP2B4 | c.1548C>T p.S516= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as COSV100396965; called by muse, mutect2, varscan2
- AUTS2 | c.882G>T p.V294= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV100714745; called by muse, mutect2, varscan2
- BRD2 | c.2331C>T p.S777= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100875540; called by muse, mutect2, varscan2
- CD163L1 | c.3177C>G p.T1059= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100549546; called by muse, mutect2, varscan2
- CFHR3 | c.876A>C p.A292= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100807378; called by muse, mutect2, varscan2
- CMTM2 | c.264T>C p.A88= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV99216343; called by muse, mutect2, varscan2
- COLEC12 | c.378A>G p.T126= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs751628660, COSV101231917; called by muse, mutect2, varscan2
- CYP17A1 | c.1122G>A p.K374= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100882068; called by muse, mutect2, varscan2
- DOCK11 | c.1453C>T p.L485= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV99352712; called by muse, mutect2, varscan2
- ESRRB | c.1074G>A p.E358= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99834689; called by muse, mutect2, varscan2
- FTMT | c.315C>T p.D105= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1427138626, COSV58419893; called by muse, mutect2, varscan2
- GALNTL5 | c.312G>T p.V104= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV101217622; called by muse, mutect2
- GFRAL | c.213G>A p.Q71= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100474410; called by muse, mutect2, varscan2
- GPR83 | c.747C>T p.I249= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV54719101, COSV99703522; called by muse, mutect2, varscan2
- GRM8 | c.690C>T p.S230= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs146491203; called by muse, mutect2, varscan2
- H1-2 | c.441G>T p.P147= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV59192137, COSV59193598; called by muse, mutect2, varscan2
- HDAC7 | c.1914C>T p.A638= (on ENST00000427332; = p.A677= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV99315392; called by muse, mutect2, varscan2
- IFI16 | c.216A>T p.I72= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99856879, COSV99858241; called by muse, mutect2, varscan2
- IGKV2-30 | c.120C>A p.S40= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- KDM4C | c.2607C>T p.N869= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs762709693, COSV101184624; called by muse, mutect2, varscan2
- LMLN | c.1680G>C p.L560= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV100218258, COSV57604709; called by muse, mutect2
- LRIT2 | c.1431G>C p.V477= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100258270; called by muse, mutect2, varscan2
- LRRTM1 | c.1347C>A p.S449= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV54441688, COSV99701635; called by muse, mutect2, varscan2
- MAG | c.741C>T p.S247= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs200159411, COSV62699404; called by muse, varscan2
- MEAF6 | c.561A>C p.P187= (on ENST00000296214 / NM_001270875.3; = p.P197= on NM_022756.6) | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99952553; called by muse, mutect2, varscan2
- NAALADL2 | c.900C>T p.I300= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs759640436, COSV69153532; called by muse, mutect2, varscan2
- NRXN1 | c.3231G>A p.E1077= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100452787; called by muse, mutect2, varscan2
- OR10H5 | c.228C>A p.A76= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV100454614; called by muse, mutect2, varscan2
- OR1C1 | c.771C>A p.A257= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV101376172, COSV68715809; called by muse, mutect2, varscan2
- OR2T6 | c.546C>T p.P182= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100861467; called by muse, mutect2
- OR8B4 | c.672C>T p.I224= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100635753, COSV100635816; called by muse, mutect2, varscan2
- PGK2 | c.327C>G p.A109= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100505281; called by muse, mutect2, varscan2
- PIGG | c.1255C>T p.L419= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99573523; called by muse, mutect2, varscan2
- PIGG | c.1701C>T p.A567= (on ENST00000453061 / NM_001127178.3; = p.A559= on NM_017733.4) | Silent (SNP) | VAF 50/188 reads (27%) | catalogued as COSV99573524; called by muse, mutect2, varscan2
- PIK3R5 | c.2526G>A p.E842= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99352745; called by muse, mutect2, varscan2
- PIWIL4 | c.2250C>T p.P750= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100133028; called by muse, mutect2, varscan2
- PKD1L1 | c.2229G>T p.P743= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99218123; called by muse, mutect2, varscan2
- PLCL1 | c.2376C>A p.A792= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV101406772; called by muse, mutect2, varscan2
- PRAMEF12 | c.912G>T p.L304= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as COSV100742957; called by muse, mutect2, varscan2
- PRDM16 | c.2028G>T p.P676= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV99575259; called by muse, mutect2, varscan2
- PUM1 | c.2256A>G p.G752= | Silent (SNP) | VAF 75/158 reads (47%) | catalogued as rs377305082; called by muse, mutect2, varscan2
- RBM10 | c.1728G>A p.E576= | Silent (SNP) | VAF 38/53 reads (72%) | catalogued as COSV100237169; called by muse, mutect2, varscan2
- REG3G | c.24C>T p.P8= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99709167; called by muse, mutect2, varscan2
- SCN10A | c.357C>A p.I119= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as COSV101479214; called by muse, mutect2, varscan2
- SCTR | c.630C>T p.A210= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as COSV50027841, COSV50033112; called by muse, mutect2, varscan2
- SERPINA12 | c.579C>A p.I193= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs749839300, COSV100369547, COSV57945662; called by muse, mutect2, varscan2
- SH3GL2 | c.1053C>A p.P351= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV101013964, COSV66052819; called by muse, mutect2, varscan2
- SLC12A4 | c.819G>T p.V273= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100311107; called by muse, mutect2, varscan2
- SLC45A3 | c.1434C>A p.T478= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV65655319, COSV65655872; called by muse, mutect2, varscan2
- SLC5A9 | c.1971C>A p.L657= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV52583012, COSV99361286; called by muse, mutect2, varscan2
- SNRPB | c.387G>T p.G129= | Silent (SNP) | VAF 57/236 reads (24%) | catalogued as COSV100293177; called by muse, mutect2, varscan2
- SPATA46 | c.339C>A p.A113= | Silent (SNP) | VAF 97/210 reads (46%) | catalogued as COSV62638041; called by muse, mutect2, varscan2
- ST8SIA3 | c.1053G>A p.Q351= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs777768220, COSV100129241; called by muse, mutect2, varscan2
- STAC3 | c.258C>T p.N86= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs148939626; ClinVar: likely benign; called by muse, mutect2, varscan2
- STK19 | c.858G>A p.G286= (on ENST00000375333 / NM_032454.1; = p.G282= on NM_004197.1) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100941604; called by muse, mutect2, varscan2
- TAS2R46 | c.273C>T p.I91= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV101113953; called by muse, varscan2
- TEK | c.1419T>C p.D473= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV101193069; called by muse, mutect2, varscan2
- THNSL2 | c.81G>T p.G27= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs1451534506, COSV59084038; called by muse, mutect2, varscan2
- TMEM9 | c.291C>T p.S97= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs748690516, COSV66243814; called by muse, mutect2, varscan2
- TNPO2 | c.1174C>T p.L392= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100790268; called by muse, mutect2, varscan2
- TRHDE | c.2742G>T p.V914= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99668707; called by muse, mutect2, varscan2
- TRIM10 | c.744G>A p.R248= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as COSV100939056; called by muse, mutect2, varscan2
- TRPM1 | c.1107A>G p.V369= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV56640587, COSV99855205; called by muse, mutect2, varscan2
- TSC2 | c.610C>T p.L204= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1439997904, COSV54769988, COSV99552348; called by muse, mutect2, varscan2
- TTN | c.27G>A p.T9= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs760305568, COSV59880306; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR33 | c.3633A>T p.P1211= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV100459466; called by muse, mutect2, varscan2
- WHRN | c.993G>T p.G331= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV99469701; called by muse, mutect2, varscan2
- WNT5B | c.27G>T p.T9= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV100148533; called by muse, mutect2, varscan2
- ZNF211 | c.1248G>T p.R416= (on ENST00000347302 / NM_198855.4; = p.R429= on NM_006385.5) | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV99559980; called by muse, mutect2, varscan2
- ZNF616 | c.1164G>A p.K388= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV100348025; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846632 G>T | 5'Flank (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- CFAP47 | c.2844+22G>T | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99934181; called by muse, mutect2, varscan2
- DNAH14 | c.749-4310T>C | Intron (SNP) | VAF 18/33 reads (55%) | catalogued as rs1471197703, COSV100835817; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446176 G>A | 3'Flank (SNP) | VAF 32/141 reads (23%) | catalogued as rs374086424; called by muse, mutect2, varscan2
- OBSCN | c.4585+2668A>G | Intron (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99471389, COSV99484153; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20182A>G | Intron (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101042731; called by muse, mutect2
- SNORD116-20 | n.2G>T | RNA (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- SNORD116-29 | n.68C>T | RNA (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SSPOP | n.2767C>A | RNA (SNP) | VAF 17/116 reads (15%) | catalogued as COSV100022057; called by muse, mutect2, varscan2
- SSPOP | n.15151G>T | RNA (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100946934; called by muse, mutect2, varscan2
- TUBA3E | c.-1C>A | 5'UTR (SNP) | VAF 26/133 reads (20%) | catalogued as COSV100471230, COSV100471506; called by muse, mutect2, varscan2
- TUBA3E | c.-2C>T | 5'UTR (SNP) | VAF 26/134 reads (19%) | catalogued as COSV57270373; called by muse, mutect2, varscan2
- Unknown | chr21:16071329 G>C | IGR (SNP) | VAF 18/44 reads (41%) | catalogued as rs1298211203; called by muse, mutect2, varscan2
